Somatic mutation profile of tumor specimen C3N-02758-01 (aliquot CPT0184040007) from CPTAC case C3N-02758, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 76.7 years (28,030 days).
Specimen C3N-02758-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41e31f9f-b7b0-4540-883c-359c8cc5b257.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02758-71 (Blood Derived Normal), aliquot CPT0184100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e2149d5-4ced-4f38-80a1-576bfba28453

The open-access MAF lists 68 somatic variants for this specimen: 45 protein-altering or splice-affecting, 16 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 16, Frame Shift Del 6, Nonsense Mutation 3, Splice Site 3, Intron 2, RNA 2, 5'UTR 2, In Frame Ins 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 166/700 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TUBB2B | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 98/1066 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1057520391; ClinVar: pathogenic; called by muse, mutect2
- ARMCX1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV65705173; called by muse, mutect2, varscan2
- BAP1 | c.1337A>G p.N446S | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs751399960, CM1515144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C6orf118 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 37/232 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs760578887; called by muse, mutect2, varscan2
- DSCAML1 | c.1642C>T p.R548W (on ENST00000321322; = p.R488W on NM_020693.4) | Missense Mutation (SNP) | VAF 94/570 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs759190973; called by muse, mutect2, varscan2
- F11 | c.1822del p.Y608Tfs*29 | Frame Shift Del (DEL) | VAF 124/626 reads (20%) | catalogued as COSV99250727; called by mutect2, pindel, varscan2
- KCNG1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 73/411 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1291103932, COSV65368885; called by muse, mutect2, varscan2
- LPA | c.3148G>A p.G1050R | Missense Mutation (SNP) | VAF 87/448 reads (19%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.928); catalogued as rs915324124, COSV60305153; called by muse, mutect2, varscan2
- MACF1 | c.18572G>T p.R6191L (on ENST00000372915; = p.R4236L on NM_012090.5) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as COSV57128168; called by muse, mutect2, varscan2
- MKLN1 | c.1560T>G p.I520M | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs760663541; called by muse, mutect2, varscan2
- PCDHGA5 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 110/457 reads (24%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.02); catalogued as rs373636717; called by muse, mutect2, varscan2
- PDILT | c.1112C>A p.A371D | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1252210326; called by muse, mutect2
- PIEZO2 | c.3241C>T p.R1081* | Nonsense Mutation (SNP) | VAF 50/294 reads (17%) | catalogued as rs985475109, COSV57450581; called by muse, mutect2, varscan2
- RASGEF1C | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764217466, COSV63180210; called by muse, mutect2, varscan2
- S100A1 | c.24del p.M9Wfs*21 | Frame Shift Del (DEL) | VAF 35/192 reads (18%) | catalogued as COSV52681432; called by mutect2, pindel, varscan2
- VRTN | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 67/297 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs138382688; called by muse, mutect2, varscan2
- ADGRF4 | c.32G>A p.C11Y | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARMCX1 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2
- ARMCX1 | c.1156C>G p.L386V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- CAPN5 | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 118/588 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CBR3 | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 87/479 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CEP250 | c.3497T>A p.L1166Q | Missense Mutation (SNP) | VAF 114/543 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- COL4A4 | c.5053del p.V1685Sfs*3 | Frame Shift Del (DEL) | VAF 104/484 reads (21%) | called by mutect2, pindel, varscan2
- ENG | c.996_998dup p.G332_R333insS | In Frame Ins (INS) | VAF 37/215 reads (17%) | called by mutect2, pindel, varscan2
- FAM160B2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM160B2 | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2
- HNRNPDL | c.774+1_774+28del p.X258_splice | Splice Site (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel
- ICAM1 | c.1426+6_1426+9del p.X476_splice | Splice Site (DEL) | VAF 18/128 reads (14%) | called by pindel, varscan2
- KIAA1328 | c.262A>C p.S88R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- KPTN | c.1000-2A>T p.X334_splice | Splice Site (SNP) | VAF 34/103 reads (33%) | called by muse, mutect2, varscan2
- LANCL3 | c.208G>C p.A70P | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2
- LRBA | c.494C>A p.T165K | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- LRRK2 | c.3392T>G p.L1131R | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MACF1 | c.21568A>T p.R7190* (on ENST00000372915; = p.R5235* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 49/301 reads (16%) | called by muse, mutect2, varscan2
- MED12 | c.6394del p.Q2132Sfs*87 | Frame Shift Del (DEL) | VAF 55/312 reads (18%) | called by pindel, varscan2
- NRDC | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- RAD51AP1 | c.414G>T p.K138N (on ENST00000228843 / NM_001130862.2; = p.K121N on NM_006479.5) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RANGAP1 | c.230dup p.E78Gfs*9 | Frame Shift Ins (INS) | VAF 21/128 reads (16%) | called by mutect2, pindel, varscan2
- RBPJL | c.535C>G p.R179G | Missense Mutation (SNP) | VAF 99/471 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- SEC14L2 | c.150G>C p.Q50H | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SEC24A | c.2032T>G p.L678V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- SNX1 | c.36_39del p.E12Dfs*49 | Frame Shift Del (DEL) | VAF 58/343 reads (17%) | called by mutect2, pindel, varscan2
- SUFU | c.1372C>T p.L458F | Missense Mutation (SNP) | VAF 115/512 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); called by muse, varscan2
- ZRANB2 | c.587del p.K196Rfs*143 (on ENST00000370920 / NM_203350.3; = p.K196Rfs*117 on NM_005455.5) | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- ARHGAP12 | c.939G>A p.G313= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs1473649952; called by muse, mutect2, varscan2
- ARMCX1 | c.294C>T p.S98= | Silent (SNP) | VAF 61/423 reads (14%) | called by muse, mutect2, varscan2
- C2CD3 | c.5604T>C p.D1868= | Silent (SNP) | VAF 48/307 reads (16%) | catalogued as rs139715233; called by muse, mutect2, varscan2
- CCDC85B | c.588G>A p.L196= | Silent (SNP) | VAF 38/214 reads (18%) | called by muse, mutect2, varscan2
- CDADC1 | c.1480T>C p.L494= | Silent (SNP) | VAF 38/167 reads (23%) | called by muse, mutect2, varscan2
- CENPV | c.351G>A p.T117= | Silent (SNP) | VAF 56/255 reads (22%) | called by muse, mutect2, varscan2
- COG7 | c.1515C>T p.C505= | Silent (SNP) | VAF 60/392 reads (15%) | catalogued as rs1416139305, COSV100207698; called by muse, mutect2, varscan2
- COL7A1 | c.4731C>T p.P1577= | Silent (SNP) | VAF 114/550 reads (21%) | catalogued as rs562521065; called by muse, mutect2, varscan2
- DDX55 | c.1434C>T p.D478= | Silent (SNP) | VAF 31/236 reads (13%) | catalogued as rs1380899547, COSV53016113; called by muse, mutect2, varscan2
- DEPDC5 | c.3324G>A p.A1108= (on ENST00000400246; = p.A1177= on NM_014662.5) | Silent (SNP) | VAF 21/319 reads (7%) | catalogued as rs367828073; called by muse, mutect2
- ESYT2 | c.2094C>T p.G698= (on ENST00000613624; = p.G622= on NM_020728.3) | Silent (SNP) | VAF 76/376 reads (20%) | called by muse, mutect2, varscan2
- GPC6 | c.57C>T p.L19= | Silent (SNP) | VAF 43/227 reads (19%) | catalogued as rs1485698502, COSV100988042; called by muse, mutect2, varscan2
- GRIN2C | c.123G>A p.P41= | Silent (SNP) | VAF 53/302 reads (18%) | catalogued as rs926284326; called by muse, mutect2, varscan2
- TRPC7 | c.582C>T p.H194= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV61455579; called by muse, mutect2, varscan2
- TSHZ3 | c.519T>G p.A173= | Silent (SNP) | VAF 72/313 reads (23%) | called by muse, mutect2, varscan2
- USP8 | c.1485G>A p.R495= | Silent (SNP) | VAF 20/127 reads (16%) | called by muse, varscan2
- AL138831.3 | n.804A>C | RNA (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- ATIC | c.1503+696A>T | Intron (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- GMPR2 | c.857+50T>C | Intron (SNP) | VAF 51/139 reads (37%) | catalogued as rs373436639; called by muse, mutect2, varscan2
- GPAA1 | c.-7C>T | 5'UTR (SNP) | VAF 40/384 reads (10%) | called by muse, mutect2
- GPAA1 | c.-5C>T | 5'UTR (SNP) | VAF 43/396 reads (11%) | called by muse, mutect2
- PNMA3 | c.*40G>A | 3'UTR (SNP) | VAF 45/347 reads (13%) | called by muse, mutect2, varscan2
- WASF4P | n.454G>C | RNA (SNP) | VAF 69/340 reads (20%) | called by muse, mutect2, varscan2
